Somatic mutation profile of tumor specimen 0DNRYP from CCDI case PBCBNL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,411 days).
Specimen 0DNRYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 324d6a71-58d6-42eb-abfc-053731fe8d18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNRYZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/036fbefd-d7b5-463b-8320-f27af3246501

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 3, Silent 2, 5'Flank 1, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP32 | c.3616C>T p.R1206C (on ENST00000310343 / NM_001378025.1; = p.R857C on NM_014715.4) | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs200179924, COSV59847056; called by muse, mutect2, varscan2
- CAVIN2 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1328721249; called by muse, mutect2, varscan2
- GPR152 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369375444; called by muse, mutect2, varscan2
- HTR1D | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757946711, COSV58447419; called by muse, mutect2, varscan2
- SHANK1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 131/539 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs767848654, COSV53252909; called by muse, mutect2, varscan2
- SIL1 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 122/586 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs371005800; called by muse, mutect2, varscan2
- SPATA7 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 94/447 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs151154007; called by muse, mutect2, varscan2
- ATG4C | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, varscan2
- BCAS4 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 96/466 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNTN3 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 18/413 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.311); called by muse, mutect2
- CSNK1A1L | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 163/693 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MOCOS | c.1021G>T p.G341* | Nonsense Mutation (SNP) | VAF 12/237 reads (5%) | called by muse, mutect2
- NCAM1 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 158/369 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NDNF | c.1606C>G p.Q536E | Missense Mutation (SNP) | VAF 62/598 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PPP4R4 | c.420_422del p.H141del | In Frame Del (DEL) | VAF 150/310 reads (48%) | called by mutect2, varscan2
- TFAP2B | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 153/767 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB18 | c.1262G>C p.C421S | Missense Mutation (SNP) | VAF 106/440 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- PPM1H | c.237C>T p.G79= | Silent (SNP) | VAF 63/327 reads (19%) | called by mutect2, varscan2
- PTCH1 | c.777C>T p.F259= | Silent (SNP) | VAF 164/850 reads (19%) | catalogued as rs750313305; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLLN | c.-46A>G | 5'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.779-20T>C | Intron (SNP) | VAF 163/675 reads (24%) | called by muse, mutect2, varscan2
- PAQR6 | c.760+34C>A | Intron (SNP) | VAF 109/500 reads (22%) | called by muse, mutect2, varscan2
- RRM2 | chr2:10122699 G>A | 5'Flank (SNP) | VAF 74/460 reads (16%) | called by mutect2, varscan2
- SPATS2L | c.1282-87G>T | Intron (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
